Gene-level copy-number profile of tumor specimen TCGA-CR-7389-01A from TCGA case TCGA-CR-7389, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 55.2 years (20,169 days).
Specimen TCGA-CR-7389-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.0b824850-3bce-49f9-8919-5f2773232fff.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7389-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d41f0723-f30c-4671-8039-55c4d53f76bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 4,379; copy number 2: 32,532; copy number 3: 16,925; copy number 4: 3,674; copy number 5: 1,442; copy number 6: 42; copy number 7: 17; copy number 12: 710; copy number 34: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7389-01A-11D-2010-01): tumor purity 0.41, ploidy 2.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 88 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:185,585,444–185,956,652, 1 gene (within-gene range 0–1): SORBS2.
- chr4:185,665,885–190,092,279, 87 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,194 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:170,418,868–170,860,380, 1 gene, copy number 5 (within-gene range 4–5): AC026316.4.
- chr3:170,448,639–170,860,993, 2 genes, copy number 5 (within-gene range 4–5): SLC7A14-AS1, SLC7A14.
- chr3:170,653,846–187,733,849, 318 genes, copy number 5–6 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 12 (broad region; genes not listed).
- chr9:14,475–1,333,953, 30 genes, copy number 6: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279.
- chr9:10,532,145–10,632,203, 3 genes, copy number 5: AL135790.2, PTPRD-AS2, AL135790.1.
- chr9:104,747,683–120,714,470, 217 genes, copy number 5 (broad region; genes not listed).
- chr14:90,847,861–106,875,071, 684 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr18:79,863,668–80,179,839, 12 genes, copy number 5 (within-gene range 2–5): KCNG2, AC114341.1, SLC66A2, AC114341.2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1.
- chr18:80,161,752–80,162,413, 1 gene, copy number 5: AC139100.2.
- chr22:17,521,514–21,637,329, 216 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,686. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
